Somatic mutation profile of tumor specimen ALCH-ADTF-TTP1-A (aliquot ALCH-ADTF-TTP1-A-1-0-D-A532-36) from ALCHEMIST case ALCH-ADTF, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 60.1 years (21,949 days).
Specimen ALCH-ADTF-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c328d1b4-a565-4b36-a539-7ad67b19ca0d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-ADTF-NB1-A (Blood Derived Normal), aliquot ALCH-ADTF-NB1-A-1-0-D-A532-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a668bdf7-94b8-428d-b294-a695f785a5fb

The open-access MAF lists 18 somatic variants for this specimen: 13 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 3, Frame Shift Del 3, 3'UTR 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 77/699 reads (11%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.395A>G p.K132R | Missense Mutation (SNP) | VAF 22/260 reads (8%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs1057519996, COSV52666637, COSV52701687, COSV52759171; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2
- ANKRD34A | c.853C>T p.R285C | Missense Mutation (SNP) | VAF 21/132 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.301); catalogued as rs782039215, COSV60161834; called by muse, mutect2, varscan2
- AQR | c.1022C>T p.A341V | Missense Mutation (SNP) | VAF 19/228 reads (8%) | SIFT tolerated (0.29); PolyPhen benign (0.065); catalogued as rs775857454; called by muse, mutect2
- CSMD3 | c.1360T>G p.F454V (on ENST00000297405 / NM_001363185.1; = p.F350V on NM_052900.3) | Missense Mutation (SNP) | VAF 14/338 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.164); catalogued as COSV52276830; called by muse, mutect2
- GABRA4 | c.1297C>A p.P433T | Missense Mutation (SNP) | VAF 21/228 reads (9%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.491); catalogued as rs1461403394; called by muse, mutect2
- AFAP1 | c.2054A>C p.D685A | Missense Mutation (SNP) | VAF 9/116 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.021); called by muse, mutect2
- COLEC12 | c.1091del p.L364Qfs*19 | Frame Shift Del (DEL) | VAF 46/340 reads (14%) | called by mutect2, pindel, varscan2
- FGF10 | c.166T>A p.S56T | Missense Mutation (SNP) | VAF 31/611 reads (5%) | SIFT tolerated (0.38); PolyPhen benign (0.05); called by muse, mutect2
- GRM1 | c.2426A>G p.N809S | Missense Mutation (SNP) | VAF 82/698 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- POLR2M | c.644C>T p.T215I | Missense Mutation (SNP) | VAF 25/274 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.173); called by muse, mutect2
- RABL6 | c.2113_2115delinsAG p.D705Rfs*65 | Frame Shift Del (DEL) | VAF 5/44 reads (11%) | called by pindel, varscan2*
- VEPH1 | c.2441_2451del p.I814Sfs*10 | Frame Shift Del (DEL) | VAF 54/443 reads (12%) | called by mutect2, pindel, varscan2
- KIAA0319L | c.1812C>T p.G604= | Silent (SNP) | VAF 12/317 reads (4%) | catalogued as rs1332323505; called by muse, mutect2
- OR2B11 | c.591T>A p.A197= | Silent (SNP) | VAF 28/221 reads (13%) | called by muse, mutect2, varscan2
- TXNDC15 | c.639C>T p.V213= | Silent (SNP) | VAF 27/371 reads (7%) | called by muse, mutect2
- SLC25A13 | c.*809C>G | 3'UTR (SNP) | VAF 22/629 reads (3%) | called by muse, mutect2
- SLC25A13 | c.*142C>T | 3'UTR (SNP) | VAF 28/600 reads (5%) | called by muse, mutect2
